Somatic mutation profile of tumor specimen BA3245D (aliquot aq-BA3245D) from BEATAML1.0 case 2829, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Primary diagnosis: Therapy related myeloid neoplasm; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.5 years (22,822 days).
Specimen BA3245D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b03163fd-a28d-41b0-8b00-77cde1992884.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3442D (Solid Tissue Normal), aliquot aq-BA3442D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b6619610-f12c-4aa8-a886-45109e0152a1

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 64/200 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FER1L6 | c.898G>T p.A300S | Missense Mutation (SNP) | VAF 11/167 reads (7%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.988); catalogued as COSV67550698; called by muse, mutect2
- ITPR3 | c.5449G>C p.E1817Q | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.354); catalogued as COSV65406048; called by muse, mutect2, varscan2
- EBF1 | c.1637C>A p.A546D | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.52); called by muse, mutect2
- TRO | c.2840C>T p.A947V | Missense Mutation (SNP) | VAF 102/216 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- FNIP2 | c.108-19663C>T | Intron (SNP) | VAF 30/71 reads (42%) | catalogued as rs765678353; called by muse, mutect2, varscan2
